Somatic mutation profile of tumor specimen TCGA-AA-3858-01A (aliquot TCGA-AA-3858-01A-01W-0900-09) from TCGA case TCGA-AA-3858, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 67.9 years (24,806 days).
Specimen TCGA-AA-3858-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 662c98ef-ae3b-49fa-9e70-91fdc8160831.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3858-10A (Blood Derived Normal), aliquot TCGA-AA-3858-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92090dd5-f31f-4bdf-88f1-b35a992d01d1

The open-access MAF lists 67 somatic variants for this specimen: 47 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 19, Nonsense Mutation 5, Frame Shift Ins 3, Frame Shift Del 1, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.4130C>A p.A1377D | Missense Mutation (SNP) | VAF 11/321 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV101202850; called by muse, mutect2
- APC | c.4056del p.E1353Nfs*62 | Frame Shift Del (DEL) | VAF 70/170 reads (41%) | catalogued as CM080063, COSV99972122; called by mutect2, pindel, varscan2
- APMAP | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774016612, COSV54173421; called by muse, mutect2, varscan2
- ATRX | c.1285A>G p.T429A | Missense Mutation (SNP) | VAF 186/251 reads (74%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.97); catalogued as rs1478989105, COSV64874701; called by muse, mutect2, varscan2
- C15orf40 | c.438A>T p.L146F | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs771058190, COSV58449621; called by muse, mutect2, varscan2
- CACNA1A | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.774); catalogued as rs763944721, COSV64192554; called by muse, mutect2
- CELF4 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58451282; called by muse, mutect2, varscan2
- CETN1 | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs753278933, COSV59121183; called by muse, varscan2
- CHST4 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768338660, COSV58296873; called by muse, mutect2, varscan2
- CSNK1A1L | c.233G>A p.W78* | Nonsense Mutation (SNP) | VAF 49/188 reads (26%) | catalogued as COSV65789556; called by muse, mutect2, varscan2
- EPHA7 | c.2683C>T p.R895* | Nonsense Mutation (SNP) | VAF 54/147 reads (37%) | catalogued as rs1035177735, COSV65179262, COSV65185064, COSV65190393; called by muse, mutect2, varscan2
- ESR1 | c.681C>A p.C227* | Nonsense Mutation (SNP) | VAF 12/88 reads (14%) | catalogued as COSV52787273; called by muse, mutect2, varscan2
- F3 | c.521G>A p.S174N | Missense Mutation (SNP) | VAF 85/162 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV61844884; called by muse, mutect2, varscan2
- FLG | c.3844G>A p.D1282N | Missense Mutation (SNP) | VAF 155/281 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs762020650, COSV64240193; called by muse, mutect2, varscan2
- HMCN1 | c.11377C>G p.R3793G | Missense Mutation (SNP) | VAF 66/350 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54892188; called by muse, mutect2, varscan2
- HOXD11 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV50910776; called by muse, mutect2, varscan2
- KRT28 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs768445733, COSV60686608; called by muse, mutect2, varscan2
- LRRTM3 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100791976; called by muse, mutect2
- MYCBP2 | c.5752A>T p.I1918L (on ENST00000357337; = p.I1956L on NM_015057.5) | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.456); catalogued as COSV62015246; called by muse, mutect2, varscan2
- NEIL2 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV52706584; called by muse, mutect2, varscan2
- OR2A12 | c.50A>C p.Q17P | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV68821255; called by muse, mutect2, varscan2
- OR4N2 | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 284/850 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs757493913, COSV60050391, COSV60050868, COSV60052488; called by muse, mutect2, varscan2
- PCDHA10 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); catalogued as rs782304851, COSV56492965; called by muse, mutect2, varscan2
- PEX5L | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); catalogued as rs745444119, COSV55843443; called by muse, mutect2, varscan2
- PRKAA2 | c.1106G>T p.R369M | Missense Mutation (SNP) | VAF 94/170 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV64803245; called by muse, mutect2, varscan2
- PRL | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.106); catalogued as COSV60591686; called by muse, mutect2, varscan2
- PRPF8 | c.4792G>A p.D1598N | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759664867, COSV59262317; ClinVar: uncertain significance; called by muse, mutect2
- PTH2 | c.88A>C p.T30P | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV54528229; called by muse, mutect2, varscan2
- SEC14L5 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs754852146, COSV52037163; called by muse, mutect2, varscan2
- SFMBT2 | c.2048G>A p.S683N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as COSV62808079; called by muse, mutect2, varscan2
- SH3BP5 | c.1147C>T p.R383* | Nonsense Mutation (SNP) | VAF 23/43 reads (53%) | catalogued as rs998191327, COSV53743727; called by muse, mutect2, varscan2
- STAB2 | c.4181A>C p.H1394P | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV66337623; called by muse, varscan2
- STXBP4 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs770185487, COSV64464511; called by muse, mutect2
- SYT16 | c.1738C>T p.Q580* | Nonsense Mutation (SNP) | VAF 21/90 reads (23%) | catalogued as COSV70856097; called by muse, mutect2, varscan2
- TCL1B | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as rs759238569, COSV61551893; called by muse, mutect2, varscan2
- TLE2 | c.1823dup p.L609Pfs*20 | Frame Shift Ins (INS) | VAF 24/36 reads (67%) | catalogued as rs763658500; called by mutect2, varscan2
- TNR | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs984032476, COSV54872423, COSV54884485; called by muse, mutect2, varscan2
- TRPC3 | c.686G>A p.R229H (on ENST00000379645 / NM_001366479.2; = p.R156H on NM_003305.2) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53372145; called by muse, mutect2, varscan2
- TTN | c.36674T>C p.V12225A (on ENST00000591111; = p.V4801A on NM_003319.4) | Missense Mutation (SNP) | VAF 29/82 reads (35%) | PolyPhen probably damaging (0.99); catalogued as COSV59988004; called by muse, mutect2, varscan2
- URB2 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763894401, COSV50984664; called by muse, mutect2, varscan2
- USP48 | c.2569C>T p.R857C | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs569663486, COSV57608959; called by muse, mutect2, varscan2
- VPS13D | c.8822G>A p.R2941Q | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs752529540, COSV50632178; called by muse, mutect2, varscan2
- WHRN | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs750380719, COSV54334177; called by muse, mutect2, varscan2
- ZNF536 | c.1499C>A p.S500Y | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62822338; called by muse, mutect2, varscan2
- CC2D1B | c.2302_2303dup p.F769Afs*5 | Frame Shift Ins (INS) | VAF 27/59 reads (46%) | called by mutect2, pindel, varscan2
- TCF12 | c.1900_1902dup p.V634dup | In Frame Ins (INS) | VAF 19/142 reads (13%) | called by mutect2, pindel, varscan2
- TP53 | c.104dup p.L35Ffs*8 | Frame Shift Ins (INS) | VAF 94/181 reads (52%) | called by mutect2, pindel, varscan2
- AMY2B | c.1182C>A p.G394= | Silent (SNP) | VAF 62/886 reads (7%) | catalogued as COSV100796561; called by muse, mutect2
- C10orf71 | c.33G>A p.A11= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs370127754; called by muse, mutect2, varscan2
- CAND2 | c.1584C>T p.A528= (on ENST00000456430 / NM_001162499.2; = p.A435= on NM_012298.3) | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV55988944; called by muse, mutect2
- DCAF10 | c.729C>T p.N243= | Silent (SNP) | VAF 45/127 reads (35%) | catalogued as COSV54287784; called by muse, mutect2, varscan2
- DHDH | c.480C>T p.H160= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs148646797; called by mutect2, varscan2
- EPHB3 | c.486C>T p.P162= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs756886601, COSV57805365; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1509C>T p.I503= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV99647726; called by muse, mutect2
- JARID2 | c.1029G>A p.T343= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as rs777430988, COSV59188043; called by muse, mutect2, varscan2
- KRT1 | c.1713C>T p.G571= | Silent (SNP) | VAF 21/32 reads (66%) | catalogued as rs1415742356, COSV52866116; called by muse, mutect2, varscan2
- MTNR1B | c.312C>T p.D104= | Silent (SNP) | VAF 68/231 reads (29%) | catalogued as rs139515067; called by muse, mutect2, varscan2
- NMBR | c.417C>T p.A139= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as rs747270958, COSV57800963; called by muse, mutect2, varscan2
- OR52N4 | c.606G>T p.L202= | Silent (SNP) | VAF 97/301 reads (32%) | catalogued as COSV100421781, COSV57892026; called by muse, mutect2, varscan2
- PCDHA12 | c.2217G>T p.L739= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV56492986; called by muse, mutect2, varscan2
- PCDHA4 | c.1824G>A p.S608= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100793865; called by muse, mutect2, varscan2
- PIWIL3 | c.1431C>T p.I477= | Silent (SNP) | VAF 57/201 reads (28%) | catalogued as rs201406937, COSV59994765; called by muse, mutect2, varscan2
- PLXDC2 | c.177C>T p.H59= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs770590576, COSV65912485, COSV65914668; called by muse, mutect2, varscan2
- RTL5 | c.936C>T p.R312= | Silent (SNP) | VAF 63/81 reads (78%) | catalogued as rs1043461984, COSV65453054; called by muse, mutect2, varscan2
- SEZ6L | c.1128C>T p.D376= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs371203903; called by muse, mutect2, varscan2
- TADA2B | c.1020C>T p.A340= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as rs768705454, COSV53827081, COSV99380733; called by muse, mutect2, varscan2
- SULT4A1 | c.742+1438G>A | Intron (SNP) | VAF 22/57 reads (39%) | catalogued as rs758955183, COSV99970473; called by muse, mutect2, varscan2
